Somatic mutation profile of tumor specimen C3N-03848-01 (aliquot CPT0237060007) from CPTAC case C3N-03848, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 56.6 years (20,674 days).
Specimen C3N-03848-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba493316-0453-406f-8260-9e7bf003ef7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03848-31 (Blood Derived Normal), aliquot CPT0237120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cdc71e4-51d8-4f9b-bda4-9a5c4d206f60

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Nonsense Mutation 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 12/348 reads (3%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2
- BRAT1 | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs1350074319; called by muse, mutect2
- CNTNAP5 | c.351G>A p.W117* | Nonsense Mutation (SNP) | VAF 16/257 reads (6%) | catalogued as rs867651102; called by muse, mutect2
- FAM171A1 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 11/313 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2
- FAM171A1 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 11/317 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.277); called by muse, mutect2
- LEO1 | c.40A>C p.S14R | Missense Mutation (SNP) | VAF 28/555 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.576); called by muse, mutect2
- MFN1 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2
- SPECC1L | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 32/600 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.341); called by muse, mutect2
- ZC2HC1A | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- ADGRG6 | c.2538G>A p.L846= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as COSV51599166; called by muse, mutect2
- CCNQ | c.501C>A p.A167= | Silent (SNP) | VAF 13/295 reads (4%) | called by muse, mutect2
- SLCO3A1 | c.1875G>T p.L625= | Silent (SNP) | VAF 26/500 reads (5%) | called by muse, mutect2
- TMEM132C | c.2104C>T p.L702= | Silent (SNP) | VAF 4/91 reads (4%) | catalogued as COSV59424901; called by muse, mutect2
- UTS2R | c.1086C>T p.C362= | Silent (SNP) | VAF 23/468 reads (5%) | called by muse, mutect2
- ZNF530 | c.15G>A p.L5= | Silent (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- AC009403.2 | n.330+32101G>A | Intron (SNP) | VAF 12/322 reads (4%) | called by muse, mutect2
- C8orf44-SGK3 | c.-464G>A | 5'UTR (SNP) | VAF 7/187 reads (4%) | catalogued as COSV66402157; called by muse, mutect2
